Somatic mutation profile of tumor specimen MP2PRT-PAMYYP-TMP1-A (aliquot MP2PRT-PAMYYP-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAMYYP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (769 days).
Specimen MP2PRT-PAMYYP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c58df3d8-3d6d-40cb-aa28-418d420ca478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAMYYP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAMYYP-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b92f87d0-7ff2-46f1-8afb-f760f397541d

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.1213G>A p.V405M (on ENST00000366508; = p.V379M on NM_015446.5) | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs756944974, COSV100403357; called by muse, mutect2, varscan2
- C1GALT1 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 197/450 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs767692066; called by muse, mutect2, varscan2
- KNDC1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 298/686 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as rs773199790; called by muse, mutect2, varscan2
- MAP2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 31/612 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs181207847, COSV99561072; called by muse, mutect2
- MCF2L | c.2737G>A p.E913K (on ENST00000375608; = p.E881K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317635526; called by muse, mutect2, varscan2
- BACH1 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 83/661 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-30 | c.349delinsCCGG p.K117delinsPE | In Frame Ins (INS) | VAF 37/200 reads (19%) | called by pindel, varscan2*
- IGKV1OR2-108 | chr2:113406870 ATTCA>GC | Missense Mutation (DEL) | VAF 20/154 reads (13%) | called by pindel, varscan2*
- NHS | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CREB3L4 | c.25C>T p.L9= | Silent (SNP) | VAF 14/427 reads (3%) | called by muse, mutect2
- LIG4 | c.2430C>G p.L810= | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- MAGEL2 | c.2019G>A p.P673= | Silent (SNP) | VAF 53/886 reads (6%) | catalogued as rs1432056131; called by muse, mutect2
- MME | c.762A>G p.R254= | Silent (SNP) | VAF 83/374 reads (22%) | called by muse, mutect2, varscan2
- MMS22L | c.474T>A p.P158= | Silent (SNP) | VAF 22/432 reads (5%) | called by muse, mutect2
